Gene-level copy-number profile of tumor specimen TARGET-40-PAMLKS-01A from TARGET case TARGET-40-PAMLKS, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.3 years (4,509 days).
Specimen TARGET-40-PAMLKS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.c602dbe2-b3bc-5aae-a3dd-43282ab2a939.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAMLKS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 393 have no estimate.
https://portal.gdc.cancer.gov/files/168f2866-946d-4b0c-aeff-bcf6343c1547

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 530; copy number 1: 261; copy number 2: 2,291; copy number 3: 7,467; copy number 4: 33,513; copy number 5: 10,944; copy number 6: 3,211; copy number 7: 426; copy number 8: 258; copy number 9: 71; copy number 10: 59; copy number 11: 100; copy number 12: 68; copy number 13: 86; copy number 14: 16; copy number 15: 104; copy number 16: 55; copy number 17: 156; copy number 18: 26; copy number 19: 25; copy number 20: 48; copy number 21: 138; copy number 25: 18; copy number 26: 103; copy number 29: 44; copy number 31: 23; copy number 32: 18; copy number 35: 64; copy number 37: 24; copy number 38: 32; copy number 40: 17; copy number 42: 9; copy number 45: 14; copy number 51: 9; copy number 55: 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr3:116,709,235–116,723,581, 2 genes: TUSC7, AC108713.1.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–4): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,302 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,274,552–72,275,159, 1 gene, copy number 11: GDI2P2.
- chr1:72,301,472–72,301,829, 1 gene, copy number 11: RPL31P12.
- chr6:32,459,821–32,731,695, 11 genes, copy number 9 (within-gene range 6–9): HLA-DRB9, HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1, MTCO3P1, AL662789.1, HLA-DQB3.
- chr6:108,041,409–108,165,854, 3 genes, copy number 51 (within-gene range 5–51): OSTM1, Y_RNA, OSTM1-AS1.
- chr8:46,784,800–47,960,178, 34 genes, copy number 11 (within-gene range 3–12): AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA.
- chr8:48,294,026–49,229,174, 20 genes, copy number 11–19 (within-gene range 3–19): IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1.
- chr8:92,460,539–93,850,075, 27 genes, copy number 13 (within-gene range 3–13): AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1.
- chr8:94,249,253–95,156,685, 33 genes, copy number 10–32: GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2.
- chr8:95,206,876–95,269,201, 2 genes, copy number 12: LINC01298, C8orf37.
- chr8:96,140,572–97,853,013, 22 genes, copy number 20 (within-gene range 5–20): AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2, CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5, SNORD3H, AP002982.1, AP002982.2, MTDH, Y_RNA, LAPTM4B, AP003357.1.
- chr8:102,154,550–102,688,906, 17 genes, copy number 17: AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, RNU6ATAC8P, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, AP002851.1, ADI1P2.
- chr8:104,330,324–112,148,825, 80 genes, copy number 10–51 (broad region; genes not listed).
- chr8:112,446,575–112,643,583, 3 genes, copy number 13: AC024996.1, RPL30P16, MIR2053.
- chr8:113,950,886–117,318,701, 22 genes, copy number 12–40: Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, AC084114.1, AP002848.1.
- chr8:119,557,086–122,428,551, 28 genes, copy number 12–26: ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR.
- chr8:124,462,485–127,742,951, 55 genes, copy number 21–38: RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,960,695, 4 genes, copy number 38: MIR1204, AC084123.1, TMEM75, MIR1205.
- chr14:95,620,914–96,567,111, 29 genes, copy number 9 (within-gene range 7–9): AL133467.2, AL133467.4, TCL6, AL133467.5, AL133467.3, AL133467.6, TCL1B, TCL1A, AL139020.1, AL133167.1, TUNAR, AL137190.1, C14orf132, BDKRB2, AL355102.2, AL355102.1, CKS1BP1, AL355102.5, BDKRB1, AL355102.4, AL355102.3, ATG2B, GSKIP, RNU2-33P, AK7, PEBP1P1, RPL23AP10, AL163051.1, PAPOLA.
- chr14:98,068,161–98,514,798, 4 genes, copy number 9 (within-gene range 7–9): AL163932.1, LINC02295, RN7SL714P, AL132719.1.
- chr15:82,744,223–90,995,629, 234 genes, copy number 10–37 (within-gene range 8–37) (broad region; genes not listed).
- chr15:90,966,340–90,988,625, 2 genes, copy number 10 (within-gene range 8–10): PRC1-AS1, Y_RNA.
- chr15:91,532,891–91,535,095, 1 gene, copy number 17: AC107958.3.
- chr15:92,281,484–93,179,999, 30 genes, copy number 11: DUXAP6, NPM1P5, ST8SIA2, AC090985.1, ENO1P2, AC090985.2, C15orf32, LINC00930, AC091544.2, AC091544.4, AC091544.5, FAM174B, AC091544.3, AC091544.7, AC091544.6, HMGN1P38, H2AZ2P1, AC091544.1, AC106028.1, AC106028.3, ASB9P1, AC106028.2, AC106028.4, CHASERR, AC013394.1, CHD2, MIR3175, RGMA, YBX2P2, AC108457.1.
- chr15:93,589,867–98,964,530, 88 genes, copy number 11–42 (within-gene range 4–42) (broad region; genes not listed).
- chr15:98,968,229–99,007,792, 1 gene, copy number 35 (within-gene range 2–35): PGPEP1L.
- chr15:99,497,812–101,295,282, 45 genes, copy number 12–31: AC015660.4, RPL7P5, MEF2A, Y_RNA, LYSMD4, DNM1P46, AC090825.2, RN7SL484P, AC090825.1, AC084855.1, ADAMTS17, AC084855.2, RNA5SP402, AC022710.1, SPATA41, CERS3-AS1, CERS3, AC027020.2, RNU6-322P, PRKXP1, AC027020.1, LINS1, RNU6-181P, ASB7, Y_RNA, AC090695.1, AC087762.1, AC087762.2, AC015712.3, AC015712.1, AC015712.6, AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2, LRRK1, AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1.
- chr15:101,295,419–101,337,428, 3 genes, copy number 21: AC023024.1, AC023024.2, PCSK6-AS1.
- chr15:101,522,597–101,933,350, 21 genes, copy number 13: AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr17:15,436,021–15,563,561, 1 gene, copy number 26 (within-gene range 2–26): TVP23C-CDRT4.
- chr17:15,502,264–18,328,056, 143 genes, copy number 15–26 (within-gene range 2–26) (broad region; genes not listed).
- chr19:27,638,483–32,244,083, 87 genes, copy number 12–55 (broad region; genes not listed).
- chr19:32,875,925–35,581,954, 117 genes, copy number 17–35 (within-gene range 8–35) (broad region; genes not listed).
- chr19:35,758,143–38,636,955, 133 genes, copy number 17–29 (within-gene range 8–29) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 261. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
